Somatic mutation profile of tumor specimen C3L-06981-54 (aliquot CPT0404530002) from CPTAC case C3L-06981, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 23.8 years (8,679 days).
Specimen C3L-06981-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 836137ba-8b58-426c-b0d1-7633b5ab7bad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06981-50 (Buccal Cell Normal), aliquot CPT0403380001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39b9c5e7-e85c-4f5f-a75a-4b76e1f84758

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPEG | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as rs748269305; called by muse, mutect2, varscan2
- ADGRV1 | c.10767T>C p.P3589= | Splice Region (SNP) | VAF 35/89 reads (39%) | called by mutect2, varscan2
- DNM2 | c.2294_2295del p.P765Hfs*58 (on ENST00000355667 / NM_001005360.3; = p.P761Hfs*58 on NM_004945.3) | Frame Shift Del (DEL) | VAF 54/268 reads (20%) | called by mutect2, varscan2
- SMC1A | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK4 | c.1233C>T p.D411= | Silent (SNP) | VAF 42/308 reads (14%) | catalogued as rs143096938, COSV62986968; called by muse, mutect2, varscan2
